FM case AD7356 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/72840ac5-ea3f-467e-9732-a7618778becd

Male, 65.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); specimen biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
